Somatic mutation profile of tumor specimen TARGET-20-PAKRZG-09A (aliquot TARGET-20-PAKRZG-09A-01D) from TARGET case TARGET-20-PAKRZG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,648 days).
Specimen TARGET-20-PAKRZG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 899cbc04-75ea-4fef-9a55-841fc327be59.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAKRZG-14A (Bone Marrow Normal), aliquot TARGET-20-PAKRZG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009c9a3c-f28e-42ce-84ce-452bfa3e764d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 106/276 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCTTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.664_665dup p.S223Tfs*69 | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
